Somatic mutation profile of tumor specimen TCGA-IS-A3K8-01A (aliquot TCGA-IS-A3K8-01A-11D-A21Q-09) from TCGA case TCGA-IS-A3K8, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Myxoid leiomyosarcoma; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 44.5 years (16,265 days).
Specimen TCGA-IS-A3K8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfc11b4a-8a1e-4429-85bf-3728af382f36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IS-A3K8-10A (Blood Derived Normal), aliquot TCGA-IS-A3K8-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82dd33a1-6998-4b38-a27e-035cb847539d

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARRB1 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV100758150; called by muse, mutect2, varscan2
- CLNK | c.405C>A p.D135E | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs759690451, COSV99905322; called by muse, mutect2, varscan2
- KBTBD7 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV65266220; called by muse, mutect2, varscan2
- MARK4 | c.1087A>G p.T363A | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as COSV99488411; called by muse, mutect2, varscan2
- RNF111 | c.539G>C p.R180P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100789088, COSV62089798; called by muse, mutect2, varscan2
- SARDH | c.949G>T p.V317F | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100897996; called by muse, mutect2, varscan2
- XPO5 | c.3214C>A p.L1072I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99541052; called by muse, mutect2
- YTHDC1 | c.791A>G p.Y264C | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100704757; called by muse, mutect2
- PLEKHO1 | c.739dup p.T247Nfs*46 | Frame Shift Ins (INS) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- SIK3 | c.3163del p.E1056Nfs*9 (on ENST00000445177 / NM_001366686.2; = p.E1014Nfs*9 on NM_025164.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- NLGN1 | c.483G>T p.P161= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV64328742; called by muse, mutect2
- SIN3A | c.3771G>T p.V1257= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV99145473; called by muse, mutect2, varscan2
